Somatic mutation profile of tumor specimen TARGET-10-PANSIZ-09A (aliquot TARGET-10-PANSIZ-09A-01D) from TARGET case TARGET-10-PANSIZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,652 days).
Specimen TARGET-10-PANSIZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cbf5512-1ab2-43bc-b8c3-845dfa914c6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANSIZ-14A (Bone Marrow Normal), aliquot TARGET-10-PANSIZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b757fea3-c1d4-4b7b-b64f-2fbdc8b0efa3

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDUA | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375300630; called by muse, mutect2, varscan2
- MAGEA6 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150966954, COSV61448665; called by muse, mutect2, varscan2
- VCAN | c.9697T>C p.F3233L | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2
- VPS52 | c.90+2T>G p.X30_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- CACHD1 | c.1224C>T p.Y408= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs374299365; called by muse, mutect2, varscan2
- DHRS7C | c.279C>T p.T93= (on ENST00000330255 / NM_001220493.2; = p.T92= on NM_001105571.3) | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- KANK4 | c.2388C>T p.A796= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as rs775052553, COSV100443173; called by muse, mutect2, varscan2
- NOL4 | c.1038G>A p.A346= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs376620423; called by muse, mutect2, varscan2
- POLR2B | c.2516-60G>A | Intron (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- SLC2A9 | c.151-92G>T | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
